Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4864, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4864-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Accession Number: [REDACTED] Report Status: Amend/A
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

***** Added Report *****

TCGA-CZ-4864

PATHOLOGIC DIAGNOSIS:

SPECIMEN LABELED "LEFT KIDNEY":

RENAL CELL CARCINOMA, (5 cm), clear cell type, Fuhrman grade III/IV.

Tumor invades renal vein.

Ureter, renal artery, and renal vein margins are negative for tumor.

Separate fibrotic nodule (6 cm) consistent with prior cryoablation; no residual viable tumor identified.

Adrenal gland with no significant pathologic change.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

CLINICAL DATA:

History: RCC S/P cryo X2.

Operation: Left radical nephrectomy.

Clinical Diagnosis: L renal tumor.

TISSUE SUBMITTED:

A/1) left kidney (s.s.), adrenal.

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patients name, unit number, and "#1 - left kidney", and consists of an 873.5 gram radical nephrectomy specimen, measuring 23.5 x 11.5 x 7 cm in total. There is a kidney measuring 10.5 x 7.2 x 5 cm, an adrenal gland measuring 3.5 x 2 x 1.2 cm, a ureter measuring 8 cm in length x 0.4 cm in diameter, a renal artery measuring 0.8 cm in length x 0.6 cm in diameter, and a bifurcating renal vein measuring 4.5 cm in length, and ranging from 0.4-1.4 cm in diameter. There are grossly two distinct masses in the renal parenchyma (T1 and T2). Mass T1 is a yellow/red, ill-defined hemorrhagic mass measuring 5 x 3.5 x 3 cm in the lower pole. T1 extends beyond the kidney to within less than 0.2 cm of Gerota's fascia (inked black). T1 also invades into the renal vein. The T1 tumor is found in both segments of the vein bifurcation, completely blocking one branch. There is also a large cortical cyst adjacent to mass T1 that measures 7 x 5.2 x 1 cm. The cyst is lined by pink, smooth tissue with multiple small white nodules. The mass T1 is located 9 cm from the ureter margin, 2 cm from the vein margin, 4 cm from the artery margin. Mass T2 has a pale tan necrotic and fibrotic component (4.9 x 4.5 x 3.5 cm) and a yellow component (6 x 4.2 x 2 cm). T2 is located in the upper pole and extends beyond the renal parenchyma. Mass T2 is 1.5 cm from the renal artery and vein margins, 8 cm from the ureter margin, and 4.2 cm from the Gerota's fascia. There is one simple renal cyst measuring 2 cm in diameter in the surface of the upper pole. No lymph nodes are grossly identified. Tissue from tumors T1 and T2 are taken for Tissue Bank and cytogenetics. Tissue from T1 is taken for electron microscopy. Normal cortex is taken for electron microscopy and immunofluorescence.

Micro A1: renal artery, vein, ureter margins, 3 frags, [REDACTED]

Micro A2: T2 in relationship to fat, 1 frag, [REDACTED]

Micro A3: mass T2, 1 frag, [REDACTED]

Micro A4: relationship of mass T2 to kidney parenchyma, 1 frag, [REDACTED]

Micro A5: additional section of mass T2 in relationship to kidney parenchyma, 1 frag, [REDACTED]

Micro A6: cross-section of adrenal gland, 1 frag, [REDACTED]

Micro A7: mass T1 in relationship to kidney parenchyma and large cyst, 1 frag, [REDACTED]

Micro A8: closest approach of mass T1 to Gerota's fascia (black-inked), 1 frag, [REDACTED]

[page 2 of 4]
Pathology Report

Micro A9: additional mass T1 in relationship to Gerota's fascia, 1 frag,

Micro A10: longitudinal section of renal vein branch partially obstructed by

tumor, 1 frag,

Micro A11: cross-section of renal vein branch completely obstructed by

tumor,

1 frag,

Micro A12: uninvolved renal parenchyma, 1 frag,

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

ADDENDUM

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

LEFT KIDNEY, NEPHRECTOMY:

DIFFUSE MESANGIAL AND FOCAL NODULAR GLOMERULOSCLEROSIS, MOST LIKELY REPRESENTING EARLY DIABETIC CHANGES WITH A SUPERIMPOSED PRIMARY VASCULAR INJURY (SEE NOTE)

MODERATELY ADVANCED CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, INCLUDING

- FOCAL GLOBAL AND SEGMENTAL GLOMERULOSCLEROSIS, MODERATE (25% OF GLOMERULI AFFECTED), MOST LIKELY SECONDARY TO VASCULAR DISEASE
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS, MODERATE (30-40% OF CORTEX)
- ARTERIAL AND ARTERIOLAR SCLEROSIS WITH HYALINOSIS, MODERATE TO SEVERE (SEE NOTE)

NOTE:

The glomeruli show diffuse sclerosis of the mesangial areas with focal nodule formation. Nodular glomerulosclerosis is most often seen in the setting of diabetic glomerulosclerosis, although similar changes also characterize paraprotein deposition diseases, immune complex-mediated glomerulonephritis, or primary forms of vascular injury with endothelial damage and subsequent mesangial scarring. Paraprotein and immune complex deposition diseases can be ruled out since the immunofluorescence microscopy shows no immunoglobulin deposits. Because the history in this patient's electronic medical record does not include mention of diabetes mellitus, additional studies were performed on the kidney tissue to further define the nature of the glomerular disease. Based on the results of the immunofluorescence examination, the process seen here is most likely mediated, at least in part, by diabetes mellitus/metabolic syndrome (or related conditions characterized by hyperglycemia and products of glycosylation) potentially with a superimposed primary form of vascular injury. Repeated endothelial or vascular injury may be reflective of an underlying inherited or acquired procoagulant state (e.g., idiopathic or systemic lupus erythematosus-associated antiphospholipid antibody syndrome, thrombophilic dysfibrinogenemia, the prothrombin G20210A mutation, the factor V Leiden mutation, and other forms of resistance to activated protein C), a prior pre-eclamptic gestation, autoimmune disorders (e.g., systemic lupus erythematosus, scleroderma, overlap syndrome), a healed episode of hemolytic-uremic syndrome or thrombotic thrombocytopenic purpura, angiotoxic drugs, physical factors (e.g., irradiation, status post bone marrow transplantation), malignant hypertension and, potentially, paraproteinemias or other metabolic diseases with an important vascular component (e.g., gout, hyperhomocysteinemia).

Moderately advanced chronic changes of the kidney parenchyma are present.

[page 3 of 4]
Pathology Report

These changes are a result of functional adaptations to nephron loss from any glomerular, tubular, interstitial, vascular, or mass-replacing process. While some degree of parenchymal scarring may be due to local compression effects of the ipsilateral masses, most of the chronic damage is likely secondary to vascular scarring. Therefore, a similar degree of chronic damage would be expected in the contralateral kidney. This patient, therefore, may be at risk for persistent or progressive proteinuria and renal insufficiency.

The kidney parenchyma has been reviewed by Dr. , Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A12) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains; an HE-stained frozen section was also evaluated by light microscopy.

The sample consists of cortex and medulla. There are 251 glomeruli present, of which 54 are globally sclerosed and 8 are segmentally sclerosed. The remaining glomeruli show expansion of the mesangial areas diffusely, with focal nodule formation. There are no discernible craters or spikes of the glomerular capillary wall basement membranes. Several double contours are identified. Approximately 30-40% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a moderate to severe degree of sclerosis with hyalinosis.

IMMUNOFLUORESCENCE MICROSCOPY REPORT

Sections of frozen tissue were incubated with antibodies specific for the heavy chains of IgG, IgA, and IgM, kappa and lambda light chains, C3, C1q, albumin, and fibrin-related antigens.

The sample consists of kidney cortex and medulla. There are 27 glomeruli present, of which 11 are globally sclerosed. There is minimal granular deposition of IgA (trace) in the mesangial areas. There is also segmental deposition of IgM and C3 in the mesangial areas. There is diffuse linear deposition of albumin (++) and IgG (++) along all basement membranes. Tubules contain reabsorbed proteins in the form of diffuse reabsorption droplets. Tubular basement membranes reveal focal deposition of C3 (++).

Many casts in the distal tubules are reactive for polyclonal IgA. Arterioles show focal C3 reactivity. There is no difference noted in the intensity of the staining for kappa and lambda light chains in the deposits, casts, or background of the tissue.

ELECTRON MICROSCOPY REPORT

Blocks: 7. Blocks examined: 3 thick sections; 0 thin sections.

Tissue submitted for electron microscopy contained no glomeruli. Thin sections were not evaluated ultrastructurally.

[Clinical history: chronic renal insufficiency (creatinine 2-3 for years), hypertension]

[page 4 of 4]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist: [REDACTED]

Report Status:

KARYOTYPE: T2;45,X,-Y[9]/46,XY[1]

METAPHASES COUNTED: 10 ANALYZED: 5 SCORED: 5 BANDING: GTG

INTERPRETATION:

No metaphases were available from specimen labeled T1, therefore the cytogenetic analysis could not be performed.

Nine of 10 metaphases from the specimen labeled T2 contained loss of the Y chromosome. Loss of the Y chromosome can be seen in nonneoplastic cells in older men, and this finding is not characteristic of any particular type of tumor.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC vs Oncocytic RCC

Source: NCI Genomic Data Commons file 5b0022a3-4a08-45ae-ac5c-584df6390d41 (TCGA-CZ-4864.831779EF-9157-4393-9C8A-78C14FCD376D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).